Somatic mutation profile of tumor specimen TARGET-10-PARENT-09A (aliquot TARGET-10-PARENT-09A-01D) from TARGET case TARGET-10-PARENT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,009 days).
Specimen TARGET-10-PARENT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a4e0640-d6b0-43cd-923b-c4a21214e664.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARENT-10A (Blood Derived Normal), aliquot TARGET-10-PARENT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4c208c3-73d0-4c40-8200-7f377db6b383

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCOR1 | c.1879C>T p.R627* | Nonsense Mutation (SNP) | VAF 12/248 reads (5%) | catalogued as COSV51984309, COSV51992684, COSV52001655; called by muse, mutect2
- BIRC6 | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- BOD1L2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by mutect2, varscan2
- ELSPBP1 | c.555G>A p.P185= | Silent (SNP) | VAF 18/286 reads (6%) | catalogued as rs773990420, COSV60412970; called by muse, mutect2
- ACTC1 | c.991-105G>A | Intron (SNP) | VAF 55/114 reads (48%) | catalogued as rs1018048937; called by muse, mutect2, varscan2
- ASNS | c.487+48G>A | Intron (SNP) | VAF 16/172 reads (9%) | catalogued as rs1216704155; called by muse, mutect2
- SGMS2 | c.895-16T>C | Intron (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
